Gene-level copy-number profile of tumor specimen TCGA-CV-7245-01A from TCGA case TCGA-CV-7245, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.0 years (22,646 days).
Specimen TCGA-CV-7245-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.61897747-36dc-4aad-b17a-fe935c605ca3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7245-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5794c85c-792d-4033-997c-74b1613735c7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,816; copy number 2: 11,309; copy number 3: 25,679; copy number 4: 16,012; copy number 5: 2,507; copy number 6: 920; copy number 7: 1,423; copy number 8: 76; copy number 9: 37; copy number 13: 22; copy number 17: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7245-01A-11D-2010-01): tumor purity 0.63, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,567 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,109,152–163,361,563, 1 gene, copy number 7 (within-gene range 6–7): LINC01192.
- chr3:163,455,568–198,222,513, 640 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr8:125,859,721–126,292,788, 1 gene, copy number 9 (within-gene range 6–9): LINC00861.
- chr8:125,951,861–129,683,770, 45 genes, copy number 9–17 (within-gene range 4–17): SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206.
- chr11:111,602,449–112,362,534, 42 genes, copy number 7 (within-gene range 2–7): SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1, AP000907.2, DLAT, PPIHP1, RNU6-893P, AP000907.3, PIH1D2, NKAPD1, TIMM8B, SDHD, AP002884.2, IL18, AP002884.1, TEX12, BCO2, KCTD9P4, MRPS36P4, RPS12P21, PTS, RPS6P16, PLET1, AP002884.3, ST13P10, LINC02762.
- chr17:75,074,306–76,387,860, 76 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr21:32,772,100–34,512,210, 52 genes, copy number 7–13 (within-gene range 2–13): C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1, ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2, SMIM11A, FAM243A, AP000322.2, SMIM34A, AP000322.1, KCNE1, AP000324.1.

Autosomal genes at a single copy (total copy number 1): 766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
